Somatic mutation profile of tumor specimen TCGA-YT-A95H-01A (aliquot TCGA-YT-A95H-01A-11D-A428-09) from TCGA case TCGA-YT-A95H, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, NOS; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 69.5 years (25,376 days).
Specimen TCGA-YT-A95H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e639aa77-571a-4919-8e1d-527abd27110a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YT-A95H-10A (Blood Derived Normal), aliquot TCGA-YT-A95H-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d3e0494-e57f-4ccb-ad28-7e9bcdc2f3e5

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 17/527 reads (3%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- ADGRG7 | c.494A>G p.Q165R | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); called by muse, mutect2
- BTBD7 | c.2566G>A p.A856T | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2
- FCAR | c.43_46dup p.G16Afs*40 | Frame Shift Ins (INS) | VAF 7/56 reads (13%) | called by muse*, mutect2
- PPT1 | c.203C>A p.S68Y (on ENST00000433473; = p.S69Y on NM_000310.4) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
